Gene-level copy-number profile of tumor specimen C3N-02572-01 (profiled together with C3N-02572-02) from CPTAC case C3N-02572, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 49.3 years (18,003 days).
Specimen C3N-02572-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 77c48e60-ac94-463a-9564-ed92fd8e5817.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02572-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/1397f024-670d-489b-ae20-ff7cb33a3226

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 16,788; copy number 3: 14,452; copy number 4: 17,387; copy number 5: 7,143; copy number 6: 1,859; copy number 7: 1,095; copy number 8: 112; copy number 9: 46; copy number 10: 26.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 72 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:12,999,676–15,880,069, 70 genes, copy number 9–10 (broad region; genes not listed).
- chr21:16,035,413–16,035,509, 1 gene, copy number 10: RNU6-426P.
- chr21:18,477,358–18,486,599, 1 gene, copy number 9 (within-gene range 8–9): AL109763.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
